Somatic mutation profile of tumor specimen TCGA-FD-A3SN-01A (aliquot TCGA-FD-A3SN-01A-12D-A22Z-08) from TCGA case TCGA-FD-A3SN, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 79.9 years (29,169 days).
Specimen TCGA-FD-A3SN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8454a5cc-0940-43ad-a270-03840f5b595b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3SN-10A (Blood Derived Normal), aliquot TCGA-FD-A3SN-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92260246-ab6c-4ddf-9604-817bcee9a788

The open-access MAF lists 465 somatic variants for this specimen: 328 protein-altering or splice-affecting, 120 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 278, Silent 120, Nonsense Mutation 26, Intron 10, Frame Shift Del 7, Splice Site 6, 5'Flank 4, In Frame Del 4, Splice Region 3, Frame Shift Ins 2, RNA 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 29/58 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs950730453, COSV54073436, COSV54083862; called by muse, mutect2, varscan2
- ERCC2 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55538855, COSV99676553; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, varscan2
- ABI1 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.017); catalogued as COSV61018424; called by muse, mutect2, varscan2
- ABL1 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.232); catalogued as COSV59324890; called by muse, mutect2, varscan2
- ACAN | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.79); PolyPhen benign (0.223); catalogued as COSV61364308; called by muse, mutect2, varscan2
- ACTL10 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV55777208; called by muse, mutect2, varscan2
- ADAM22 | c.2215A>T p.I739L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55982717; called by muse, mutect2, varscan2
- ADCY7 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs538515875; called by muse, mutect2, varscan2
- AHCTF1 | c.3973G>A p.E1325K (on ENST00000366508; = p.E1299K on NM_015446.5) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV58252350; called by muse, mutect2, varscan2
- ALAS1 | c.1649G>A p.R550K | Missense Mutation (SNP) | VAF 204/277 reads (74%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV59628631; called by muse, mutect2, varscan2
- ALB | c.803A>T p.E268V | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55739960; called by muse, mutect2, varscan2
- ALKBH8 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150490382; called by muse, mutect2, varscan2
- ALS2 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV51889406; called by muse, mutect2, varscan2
- ANAPC2 | c.2306C>T p.S769L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs1171681598, COSV100119259; called by muse, mutect2
- AOAH | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV51739585, COSV51745458; called by muse, mutect2, varscan2
- ARHGAP5 | c.4357G>A p.E1453K (on ENST00000345122 / NM_001030055.2; = p.E1452K on NM_001173.3) | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as COSV53734979, COSV53735362; called by muse, mutect2, varscan2
- ARHGAP9 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs375759169; called by muse, mutect2, varscan2
- ARID2 | c.2233C>T p.Q745* | Nonsense Mutation (SNP) | VAF 41/95 reads (43%) | catalogued as COSV100535893; called by muse, mutect2, varscan2
- ARID2 | c.2500C>T p.Q834* | Nonsense Mutation (SNP) | VAF 37/103 reads (36%) | catalogued as COSV57600420; called by muse, mutect2, varscan2
- ASH1L | c.7885G>C p.D2629H (on ENST00000368346 / NM_001366177.2; = p.D2624H on NM_018489.3) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV64210417; called by muse, mutect2, varscan2
- ASIC5 | c.91C>G p.P31A | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as COSV72232975; called by muse, mutect2, varscan2
- ATL3 | c.1234C>G p.R412G | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV60297119; called by muse, mutect2, varscan2
- ATP5F1C | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV59622217; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs893279066, COSV52270490; called by muse, mutect2, varscan2
- ATXN2 | c.2006C>T p.S669L (on ENST00000550104; = p.S509L on NM_002973.4) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs774827848, COSV66484550; called by muse, mutect2, varscan2
- AXDND1 | c.2409C>G p.I803M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV62644964; called by muse, mutect2, varscan2
- BAZ2B | c.4660G>A p.E1554K | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs534478288, COSV58604988; called by muse, mutect2, varscan2
- BBX | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as COSV57883807; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.006); catalogued as COSV57281029; called by muse, mutect2, varscan2
- BLOC1S4 | c.542C>G p.S181W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57900922, COSV57901149; called by muse, mutect2, varscan2
- BMP6 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139361183; called by muse, mutect2, varscan2
- BPNT2 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV52908184; called by muse, mutect2
- BPTF | c.4852G>A p.D1618N | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV58841276; called by muse, mutect2, varscan2
- C16orf86 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773590886, COSV54752528; called by muse, mutect2, varscan2
- C1orf141 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1339905071, COSV63992966; called by muse, mutect2, varscan2
- C4orf33 | c.61A>G p.I21V | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs762481004, COSV55416444; called by muse, mutect2, varscan2
- CARD16 | c.521A>G p.H174R | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs1318362700, COSV65213165; called by muse, mutect2, varscan2
- CARNS1 | c.1402G>C p.D468H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV57052253; called by muse, mutect2, varscan2
- CARS2 | c.233G>A p.C78Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1482739493, COSV57287363; called by muse, mutect2, varscan2
- CAVIN1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV63812298; called by muse, mutect2, varscan2
- CCDC180 | c.1992C>G p.F664L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV63832230; called by muse, mutect2, varscan2
- CCDC88B | c.3102C>G p.A1034= | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as COSV57266615, COSV57266981; called by muse, mutect2, varscan2
- CCND3 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV57827644, COSV57827650; called by muse, mutect2, varscan2
- CDH15 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs372201468; called by muse, mutect2
- CDH23 | c.6593C>A p.A2198D | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56475164; called by muse, mutect2, varscan2
- CDK12 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.928); catalogued as COSV71001627; called by muse, mutect2, varscan2
- CDON | c.3277G>A p.G1093S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.204); catalogued as COSV54999938; called by muse, mutect2
- CEP350 | c.3422G>A p.R1141K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.527); catalogued as COSV62605810; called by muse, mutect2, varscan2
- CHD6 | c.5686C>A p.P1896T | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV64692513; called by muse, mutect2, varscan2
- CHD9 | c.4411G>A p.E1471K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV54612959, COSV54615159, COSV99529580; called by muse, mutect2, varscan2
- CHPT1 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1223211798, COSV57533968, COSV99977855; called by muse, mutect2, varscan2
- CILP2 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV52277330; called by muse, mutect2, varscan2
- CKAP4 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV65172900; called by muse, mutect2, varscan2
- CMIP | c.2155T>C p.C719R (on ENST00000537098 / NM_198390.2; = p.C625R on NM_030629.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67699333; called by muse, mutect2, varscan2
- CNOT1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100409942, COSV100409948; called by muse, mutect2
- COBLL1 | c.2228C>T p.S743L (on ENST00000392717; = p.S705L on NM_014900.5) | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV52071394; called by muse, mutect2, varscan2
- COL16A1 | c.1218C>A p.D406E | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.958); catalogued as COSV54709907; called by muse, mutect2, varscan2
- CREB3L4 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV55210649; called by muse, mutect2, varscan2
- CREB3L4 | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV55132618; called by muse, varscan2
- CRYZL1 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV51678462; called by muse, mutect2, varscan2
- CSK | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54974756; called by muse, mutect2, varscan2
- CSNK1A1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.189); catalogued as COSV55794349, COSV55796338; called by muse, mutect2, varscan2
- CYB5B | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57174919; called by muse, mutect2
- DBF4 | c.961A>G p.S321G | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV55997807; called by muse, mutect2, varscan2
- DCTPP1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60000699; called by muse, mutect2, varscan2
- DDI2 | c.506-1G>C p.X169_splice | Splice Site (SNP) | VAF 81/238 reads (34%) | catalogued as rs1464698467, COSV60780415; called by muse, varscan2
- DDI2 | c.1162C>G p.Q388E | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as COSV60779098, COSV60780421; called by muse, mutect2, varscan2
- DGKK | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV65708500; called by muse, mutect2, varscan2
- DISP3 | c.2786A>G p.Q929R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); catalogued as COSV53831746; called by muse, mutect2, varscan2
- DIXDC1 | c.865G>A p.E289K (on ENST00000440460 / NM_001037954.4; = p.E78K on NM_033425.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV59462586; called by muse, mutect2, varscan2
- DLD | c.39+2T>A p.X13_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52738770; called by muse, varscan2
- DOCK9 | c.2876C>T p.S959L (on ENST00000376460 / NM_001366676.2; = p.S960L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV59635536, COSV59641786; called by muse, mutect2, varscan2
- DPP10 | c.2157A>G p.I719M | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.148); catalogued as rs781605645, COSV59701770; called by muse, mutect2, varscan2
- DPYD | c.401A>T p.D134V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60080871; called by muse, mutect2, varscan2
- DSC1 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs538161979, COSV57144180; called by muse, mutect2, varscan2
- DSG3 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as COSV57127780; called by muse, mutect2, varscan2
- DUSP16 | c.1504C>G p.P502A | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV53808622; called by muse, mutect2, varscan2
- DUSP4 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.524); catalogued as rs933174088, COSV53546694; called by muse, mutect2, varscan2
- EBF3 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV62477532, COSV62481364; called by muse, mutect2, varscan2
- ECHDC2 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1285675770, COSV100597799, COSV64300701, COSV64301721; called by muse, mutect2, varscan2
- EHMT2 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs912280110, COSV64993996; called by muse, mutect2, varscan2
- EIF2AK3 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV57549773; called by muse, mutect2, varscan2
- ERBB3 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.609); catalogued as COSV57257862; called by muse, mutect2, varscan2
- ERCC3 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV53428320; called by muse, mutect2, varscan2
- ERCC4 | c.2716G>C p.A906P | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV61312899; called by muse, mutect2, varscan2
- ESYT2 | c.1177G>A p.E393K (on ENST00000613624; = p.E317K on NM_020728.3) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1378698407, COSV51753396; called by muse, mutect2, varscan2
- EXD1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as COSV59255163; called by muse, mutect2, varscan2
- EZH2 | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57456970; called by muse, mutect2, varscan2
- FAM83G | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as rs758694379, COSV58759958; called by muse, mutect2
- FAM83H | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs948210399, COSV66353643, COSV66354317; called by muse, mutect2, varscan2
- FCHO1 | c.211_216del p.W71_E72del | In Frame Del (DEL) | VAF 10/31 reads (32%) | catalogued as COSV53183546; called by mutect2, pindel, varscan2
- FLVCR2 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV53163224; called by muse, mutect2, varscan2
- FMO2 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV52949039; called by muse, mutect2, varscan2
- FOS | c.786G>T p.M262I | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57839894; called by muse, mutect2, varscan2
- FOXJ2 | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV50820575; called by mutect2, varscan2
- FOXP2 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV63481953; called by muse, mutect2, varscan2
- FRAS1 | c.10025C>T p.S3342L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375437443; called by muse, mutect2, varscan2
- FSIP2 | c.19174G>A p.E6392K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV58091894; called by muse, mutect2, varscan2
- FSIP2 | c.19402G>C p.D6468H | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV100554024, COSV58091906; called by muse, mutect2, varscan2
- FUNDC2 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65670322, COSV65670422, COSV65671283; called by muse, mutect2, varscan2
- FUZ | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV58242189; called by muse, mutect2, varscan2
- GABRR3 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760476762, COSV72084269; called by muse, mutect2, varscan2
- GALK1 | c.813C>G p.S271R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.226); catalogued as COSV52329196; called by muse, mutect2, varscan2
- GNA13 | c.598A>G p.R200G | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV71474990; called by muse, mutect2, varscan2
- GNL1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV64835374; called by muse, mutect2, varscan2
- GNS | c.1087C>G p.Q363E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV50695502; called by muse, mutect2, varscan2
- GPC5 | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV65611373; called by muse, mutect2, varscan2
- GPR156 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59941170; called by muse, mutect2, varscan2
- GPR158 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66275912; called by muse, mutect2, varscan2
- GPR62 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV59055207; called by muse, mutect2, varscan2
- GSTT2B | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1261516675; called by muse, mutect2, varscan2
- GTF2E2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.762); catalogued as rs780571452, COSV63478716; called by muse, mutect2, varscan2
- H2AX | c.290_316del p.L97_G106delinsR | In Frame Del (DEL) | VAF 20/114 reads (18%) | catalogued as COSV53829270; called by mutect2, pindel
- HEATR5A | c.4330G>A p.D1444N | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.046); catalogued as COSV66343205; called by muse, mutect2, varscan2
- HIF1A | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 20/25 reads (80%) | catalogued as COSV100049174; called by muse, mutect2, varscan2
- HK1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV53856048; called by muse, mutect2, varscan2
- HMGCLL1 | c.978G>C p.L326F | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51447968, COSV99231300; called by muse, mutect2, varscan2
- HTATSF1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV54479888; called by muse, mutect2, varscan2
- IGHV1-2 | c.164G>A p.W55* | Nonsense Mutation (SNP) | VAF 57/108 reads (53%) | catalogued as rs1285378106; called by muse, mutect2, varscan2
- IGHV3-11 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.393); catalogued as rs576921959; called by muse, mutect2, varscan2
- IGHV3-48 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.196); catalogued as rs1321987536; called by muse, mutect2, varscan2
- IGHV3-7 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.43); catalogued as rs782620652; called by muse, mutect2, varscan2
- IMMT | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); catalogued as COSV54488157, COSV54490341; called by muse, mutect2, varscan2
- INCA1 | c.507G>C p.E169D (on ENST00000574617 / NM_001167986.1; = p.E154D on NM_213726.2) | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.71); catalogued as COSV61788506; called by muse, mutect2, varscan2
- INO80E | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.685); catalogued as rs946242665, COSV54230948; called by muse, mutect2, varscan2
- IST1 | c.1084G>C p.D362H (on ENST00000535424 / NM_001270976.1; = p.K347N on NM_014761.4) | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58664783; called by muse, mutect2, varscan2
- ITGAV | c.298A>T p.I100F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV53715528, COSV53721051; called by muse, varscan2
- KATNIP | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55185557; called by muse, mutect2, varscan2
- KCNH8 | c.2743G>T p.V915L | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV60462543, COSV60469525; called by muse, mutect2, varscan2
- KCNK2 | c.155C>T p.T52M (on ENST00000444842 / NM_001017425.3; = p.T37M on NM_014217.4) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); catalogued as rs557780618, COSV67207755; called by muse, mutect2, varscan2
- KDELR3 | c.195G>A p.V65= | Splice Region (SNP) | VAF 61/110 reads (55%) | catalogued as COSV53248745; called by muse, mutect2, varscan2
- KLC3 | c.1073G>C p.R358P | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67269137; called by muse, mutect2, varscan2
- KLF6 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.802); catalogued as COSV51495256; called by muse, mutect2, varscan2
- KLHDC7A | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as rs775606176, COSV68770316; called by muse, mutect2, varscan2
- KMT2B | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1226451581, COSV55864713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KPNA4 | c.1503T>G p.I501M | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV62076338; called by muse, mutect2, varscan2
- KRIT1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV60667471, COSV60669171; called by muse, mutect2, varscan2
- KRTCAP2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55279533; called by muse, mutect2, varscan2
- LAMA2 | c.8701C>T p.P2901S | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV70351533; called by muse, mutect2, varscan2
- LAPTM4A | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as COSV51533159; called by muse, mutect2, varscan2
- LCN2 | c.138+1G>A p.X46_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | catalogued as COSV52981344; called by muse, mutect2, varscan2
- LIFR | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54694145; called by muse, varscan2
- LINS1 | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV59079944; called by muse, mutect2, varscan2
- LNX1 | c.614G>A p.R205Q (on ENST00000263925 / NM_001126328.3; = p.R109Q on NM_032622.2) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as rs201126543, COSV55788429; called by muse, mutect2, varscan2
- LONRF1 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs374942182; called by muse, mutect2, varscan2
- LRCH3 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV58394128; called by muse, mutect2, varscan2
- LRRCC1 | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV64484263; called by muse, mutect2, varscan2
- LTBP1 | c.4456G>A p.E1486K (on ENST00000404816 / NM_206943.4; = p.E1160K on NM_000627.4) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV55381905; called by muse, mutect2, varscan2
- LUC7L2 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs560389628, COSV54927995; called by muse, mutect2, varscan2
- MAFK | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as rs143840628; called by muse, mutect2
- MAGEF1 | c.196_202del p.A66Qfs*9 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | catalogued as COSV58634098; called by mutect2, pindel, varscan2
- MAP2 | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV52298483, COSV52302766; called by muse, mutect2, varscan2
- MAP6 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.055); catalogued as rs775786346, COSV59076657; called by muse, mutect2
- MAPRE2 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as COSV55817252; called by muse, mutect2, varscan2
- MCCC1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55610007; called by muse, mutect2, varscan2
- MEGF8 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs780023172, COSV52092339; called by muse, mutect2, varscan2
- MFSD1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs769367528, COSV51839650; called by muse, varscan2
- MN1 | c.3337T>G p.S1113A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.98); catalogued as COSV56559908; called by muse, mutect2, varscan2
- MRPS22 | c.785G>A p.R262H (on ENST00000310776 / NM_001363893.1; = p.R263H on NM_020191.4) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as rs1001683797, COSV60350659; called by muse, mutect2, varscan2
- MS4A2 | c.577del p.G194Vfs*29 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as COSV54013106; called by mutect2, pindel, varscan2
- MUC17 | c.2878G>T p.E960* | Nonsense Mutation (SNP) | VAF 172/770 reads (22%) | catalogued as COSV100072672; called by muse, varscan2
- MYH7B | c.1047G>A p.M349I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53422353; called by muse, mutect2, varscan2
- MYNN | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV62991663; called by muse, mutect2, varscan2
- MYO16 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51804556, COSV51819169; called by muse, mutect2, varscan2
- MYO9A | c.5053G>A p.E1685K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.175); catalogued as COSV61853885; called by muse, mutect2, varscan2
- NEK10 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58286159; called by muse, mutect2, varscan2
- NEPRO | c.1568_1594del p.I523_E532delinsK | In Frame Del (DEL) | VAF 42/124 reads (34%) | catalogued as COSV55606901; called by mutect2, pindel
- NHS | c.3929C>G p.T1310S | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV66278370; called by muse, mutect2, varscan2
- NLRP1 | c.2901G>T p.M967I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52571149, COSV99333213; called by muse, mutect2, varscan2
- NLRP3 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs763186819, COSV60221860; called by muse, mutect2, varscan2
- NPPB | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64687710; called by mutect2, varscan2
- NRIP2 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as COSV61701744; called by muse, varscan2
- OIT3 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs139078371; called by muse, mutect2, varscan2
- OR7A5 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV59234924; called by muse, mutect2, varscan2
- OSBPL11 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs944709220, COSV56174941, COSV56176511; called by muse, mutect2, varscan2
- OSR2 | c.399G>C p.M133I | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52557914; called by muse, mutect2, varscan2
- PAXBP1 | c.1792A>G p.I598V | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as rs746568370, COSV51610453; called by muse, mutect2, varscan2
- PCIF1 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.406); catalogued as rs1370088899, COSV59818769; called by muse, mutect2, varscan2
- PCLO | c.6859G>A p.D2287N | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.196); catalogued as COSV61648388; called by muse, mutect2, varscan2
- PCNT | c.4888T>G p.S1630A | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV64030425; called by muse, mutect2, varscan2
- PCNT | c.4889C>A p.S1630* | Nonsense Mutation (SNP) | VAF 58/112 reads (52%) | catalogued as COSV100855349; called by muse, mutect2, varscan2
- PCNX2 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV50829769; called by muse, mutect2, varscan2
- PCNX4 | c.2638C>G p.L880V (on ENST00000406854 / NM_001330177.2; = p.L646V on NM_022495.5) | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58305692; called by muse, mutect2, varscan2
- PDE4DIP | c.4931C>T p.S1644F | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.236); catalogued as rs782334544, COSV57680634, COSV57709011; called by muse, mutect2, varscan2
- PHTF1 | c.1804-1G>A p.X602_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | catalogued as rs202217945; called by muse, mutect2, varscan2
- PIGZ | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV53014105; called by muse, mutect2, varscan2
- PIWIL1 | c.1139C>G p.A380G | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV55348965, COSV99805979; called by muse, mutect2, varscan2
- PLCE1 | c.3176C>G p.P1059R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.26); catalogued as rs780768832, COSV53359796; called by muse, mutect2, varscan2
- PLEC | c.8535G>C p.E2845D (on ENST00000322810 / NM_201380.4; = p.E2735D on NM_000445.5) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV59627565; called by muse, mutect2, varscan2
- PLEC | c.7785G>C p.E2595D (on ENST00000322810 / NM_201380.4; = p.E2485D on NM_000445.5) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV59644046; called by muse, mutect2, varscan2
- PLEKHA6 | c.2815del p.L939* | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as COSV55335087; called by mutect2, pindel, varscan2
- PLEKHA6 | c.841G>C p.G281R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55336322; called by muse, mutect2, varscan2
- PLEKHA6 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV55331056, COSV55334020; called by muse, mutect2, varscan2
- PLEKHA6 | c.546G>C p.E182D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55333860, COSV55336337; called by muse, mutect2, varscan2
- PLPPR4 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64566838; called by muse, mutect2, varscan2
- PNPT1 | c.1495+1G>A p.X499_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as COSV53178630; called by muse, mutect2, varscan2
- POLN | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV67026247; called by muse, mutect2, varscan2
- POLQ | c.917C>A p.S306* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV51747673, COSV51761701; called by muse, mutect2, varscan2
- PPP1CB | c.490G>C p.V164L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV56091133; called by muse, mutect2, varscan2
- PPP1R16A | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs757432715, COSV52953874; called by muse, mutect2, varscan2
- PRKDC | c.7732G>A p.E2578K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs975482229; called by muse, mutect2, varscan2
- PRPF18 | c.369G>C p.L123F | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV60725763; called by muse, mutect2, varscan2
- RAB3IL1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as rs998898643, COSV57118098; called by muse, mutect2
- RAD51C | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV53620946; called by muse, mutect2, varscan2
- RAD54B | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV60252944; called by muse, mutect2, varscan2
- RANBP2 | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as rs570157899; called by muse, mutect2, varscan2
- RARG | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58432896; called by muse, mutect2, varscan2
- RBM28 | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV56163825, COSV99775948; called by muse, mutect2, varscan2
- RDH10 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as COSV53583306; called by muse, mutect2, varscan2
- REPS1 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.202); catalogued as COSV57812238; called by muse, mutect2, varscan2
- REV1 | c.3497A>G p.N1166S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs758902128, COSV51482379; called by muse, mutect2, varscan2
- REXO5 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV54473273; called by muse, mutect2
- RFWD3 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV63098287; called by muse, mutect2, varscan2
- RND1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV59045687; called by muse, mutect2, varscan2
- RP1L1 | c.4333G>A p.E1445K | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.444); catalogued as COSV66757447; called by muse, mutect2, varscan2
- RREB1 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV58560465, COSV58560971; called by muse, mutect2, varscan2
- RRM2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as COSV58817308; called by muse, mutect2, varscan2
- RRS1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs766463381, COSV52557140; called by muse, mutect2, varscan2
- SCFD2 | c.1696C>A p.H566N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV66374299; called by muse, mutect2, varscan2
- SEPTIN3 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.857); catalogued as COSV52170409; called by muse, mutect2, varscan2
- SERPIND1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs1297371941, COSV53139697; called by muse, mutect2, varscan2
- SERPIND1 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV53139715; called by muse, mutect2, varscan2
- SIGLEC5 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55781406; called by muse, mutect2, varscan2
- SIRPB2 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778195889, COSV63124482; called by muse, mutect2, varscan2
- SLC38A9 | c.1353G>A p.M451I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV59424785; called by muse, mutect2, varscan2
- SLC9A1 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.18); catalogued as COSV56054929; called by muse, mutect2, varscan2
- SLC9A4 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as rs768703415, COSV99762579; called by muse, mutect2, varscan2
- SLC9A5 | c.1341G>C p.L447F | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55363305; called by muse, mutect2, varscan2
- SLITRK5 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61524252; called by muse, mutect2, varscan2
- SMARCA2 | c.3494A>C p.Q1165P | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61809760; called by muse, mutect2, varscan2
- SNCB | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs778391533, COSV59435751; called by muse, mutect2
- SNCB | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs745388495, COSV59435758; called by muse, mutect2
- SNX22 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs769082872, COSV55520657; called by muse, mutect2, varscan2
- SPAG4 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.075); catalogued as COSV65330136; called by muse, mutect2, varscan2
- SPG11 | c.5394G>C p.E1798D | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55998504; called by muse, mutect2, varscan2
- SPINK5 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56258180; called by muse, mutect2, varscan2
- SPINK5 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as COSV56258202; called by muse, mutect2, varscan2
- SPTAN1 | c.6736G>A p.E2246K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63988347; called by muse, mutect2, varscan2
- SREBF2 | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as COSV63331833; called by muse, mutect2, varscan2
- SRP19 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs757766883, COSV51582897; called by muse, mutect2, varscan2
- SRRM2 | c.1949G>A p.R650K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV57076620; called by muse, mutect2, varscan2
- STAG1 | c.3060G>C p.K1020N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV52615861; called by muse, mutect2, varscan2
- STK35 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.809); catalogued as COSV55691796; called by muse, mutect2, varscan2
- STXBP5L | c.3012G>A p.M1004I | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV56522828; called by muse, mutect2, varscan2
- STYXL2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs144186156; called by muse, mutect2, varscan2
- SULT2A1 | c.850T>C p.W284R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442952150, COSV55765457; called by muse, mutect2, varscan2
- SUPT5H | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.018); catalogued as COSV100782074, COSV63240827; called by muse, mutect2, varscan2
- SYNE2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV59958100, COSV59968446; called by muse, mutect2, varscan2
- SYT14 | c.1631A>T p.Q544L | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs754630501, COSV55058443; called by muse, mutect2, varscan2
- TACC2 | c.4142C>T p.S1381F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as COSV57762402; called by muse, mutect2, varscan2
- TBX15 | c.883C>T p.R295* (on ENST00000369429 / NM_001330677.2; = p.R189* on NM_152380.3) | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV52867625; called by muse, mutect2, varscan2
- TECRL | c.330T>C p.C110= | Splice Region (SNP) | VAF 20/63 reads (32%) | catalogued as COSV67088622; called by muse, mutect2, varscan2
- TENM3 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV69313276; called by muse, mutect2, varscan2
- TGS1 | c.849C>A p.N283K | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52701312; called by muse, mutect2, varscan2
- THRAP3 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.882); catalogued as COSV63568748; called by muse, mutect2, varscan2
- THSD1 | c.1681G>C p.D561H | Missense Mutation (SNP) | VAF 73/105 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51630008; called by muse, mutect2, varscan2
- TICRR | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1258984120, COSV51543807; called by muse, mutect2, varscan2
- TLX1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100930059, COSV64622648; called by muse, mutect2, varscan2
- TMEFF2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.241); catalogued as COSV55835859; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.787); catalogued as COSV64101697; called by muse, mutect2, varscan2
- TNS3 | c.2747C>T p.S916L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs575487797, COSV60786311; called by muse, mutect2, varscan2
- TOGARAM2 | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); catalogued as COSV65422686; called by muse, mutect2, varscan2
- TOX | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV63848300; called by muse, mutect2, varscan2
- TRAF3IP2 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV60676412; called by muse, mutect2, varscan2
- TRIM14 | c.863C>A p.T288K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.589); catalogued as rs752551468, COSV52965287; called by muse, mutect2
- TRIM50 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs202100558; called by muse, mutect2, varscan2
- TSC1 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53769623; called by muse, mutect2, varscan2
- TSKS | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV55874324, COSV55876886; called by muse, mutect2, varscan2
- TSPOAP1 | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.559); catalogued as rs372248342; called by muse, mutect2, varscan2
- TTC31 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 94/288 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52036228; called by muse, mutect2, varscan2
- TTC33 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs918450421, COSV61802755; called by muse, mutect2, varscan2
- TTC7A | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147914967, CM143009; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.82871G>C p.G27624A (on ENST00000591111; = p.G20200A on NM_003319.4) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | PolyPhen probably damaging (0.999); catalogued as COSV100589900, COSV60180991; called by muse, mutect2, varscan2
- TTN | c.76501G>C p.E25501Q (on ENST00000591111; = p.E18077Q on NM_003319.4) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | PolyPhen possibly damaging (0.698); catalogued as COSV60181030, COSV99045784; called by muse, mutect2, varscan2
- TUT1 | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV53470913; called by muse, mutect2, varscan2
- TYW1 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55888082; called by muse, mutect2, varscan2
- USP34 | c.9317G>A p.S3106N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs781541100, COSV68403434; called by muse, mutect2, varscan2
- VPS35L | c.849G>C p.K283N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51986807; called by muse, mutect2, varscan2
- VPS37B | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57360975; called by muse, mutect2, varscan2
- WDR11 | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54790302; called by muse, mutect2, varscan2
- WDR26 | c.2256T>G p.I752M (on ENST00000414423 / NM_001379403.1; = p.I652M on NM_025160.7) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV54357471; called by muse, mutect2, varscan2
- YWHAB | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV62304524; called by muse, mutect2, varscan2
- ZFC3H1 | c.3623C>G p.T1208R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV66434187; called by muse, mutect2, varscan2
- ZFYVE26 | c.5335C>T p.H1779Y | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs376671127; called by muse, mutect2, varscan2
- ZNF107 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as COSV61328949, COSV61330039; called by muse, mutect2, varscan2
- ZNF263 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV54597309; called by muse, mutect2, varscan2
- ZNF521 | c.2672G>A p.C891Y | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64129236; called by muse, mutect2, varscan2
- ZNF557 | c.55G>A p.E19K (on ENST00000414706 / NM_001044388.2; = p.E26K on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.47); PolyPhen benign (0.291); catalogued as COSV53274596; called by muse, mutect2, varscan2
- ZNF600 | c.1796G>C p.R599T | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.105); catalogued as COSV57742494, COSV57743218; called by muse, mutect2
- ZNF622 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV58074645; called by muse, mutect2, varscan2
- ZNF665 | c.730C>T p.R244* (on ENST00000600412; = p.R309* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/201 reads (30%) | catalogued as rs749136964, COSV67217380; called by muse, mutect2, varscan2
- ZNF714 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.803); catalogued as COSV52513544; called by muse, mutect2, varscan2
- ZNF718 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV68140523; called by muse, mutect2, varscan2
- ZRANB2 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV54672910; called by muse, mutect2, varscan2
- ADGRF3 | c.2715C>A p.Y905* (on ENST00000311519 / NM_001145168.1; = p.Y706* on NM_153835.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- ARID1A | c.1178_1188del p.Q393Rfs*3 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- ART1 | c.829T>G p.C277G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- BFAR | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- CEP192 | c.4208G>A p.W1403* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- CREB5 | c.1408C>T p.Q470* (on ENST00000357727 / NM_182898.4; = p.Q463* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- CSMD1 | c.361T>C p.W121R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.017); called by muse, mutect2
- ECD | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- EPHX3 | c.380_393del p.V127Afs*42 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel
- G3BP1 | c.1002_1003insGGGTG p.R335Gfs*2 | Frame Shift Ins (INS) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- GPR37L1 | c.176_177insCAA p.Y59_V60insN | In Frame Ins (INS) | VAF 13/28 reads (46%) | called by mutect2, pindel, varscan2
- HIPK3 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- HSPA12B | c.1901T>A p.L634H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IFI44L | c.1003dup p.M335Nfs*25 | Frame Shift Ins (INS) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- LDB1 | c.590G>A p.W197* (on ENST00000425280 / NM_001321612.2; = p.W161* on NM_003893.5) | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | called by muse, varscan2
- METTL25 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- MRPL30 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- NAMPT | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- NF1 | c.2855_2865del p.L952Yfs*19 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- NFAT5 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- NPFFR1 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- PI4K2B | c.284C>A p.S95* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- PLCB1 | c.2517G>C p.K839N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- PLEC | c.7213G>T p.E2405* (on ENST00000322810 / NM_201380.4; = p.E2295* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- PLPP1 | c.819_821del p.T274del | In Frame Del (DEL) | VAF 26/68 reads (38%) | called by pindel, varscan2
- PTPN21 | c.351-2A>G p.X117_splice | Splice Site (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2
- ST14 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- STAC3 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- SYNE3 | c.1589_1604del p.D530Afs*132 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- TNPO3 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- TXNDC2 | c.1636G>A p.E546K (on ENST00000306084 / NM_001098529.2; = p.E479K on NM_032243.6) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2
- WDR3 | c.2793G>C p.K931N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.136); called by muse, mutect2
- ABLIM1 | c.717G>A p.L239= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs774775068, COSV53310286; called by muse, mutect2, varscan2
- ACD | c.138T>C p.R46= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs2303761, COSV54668827; called by muse, mutect2, varscan2
- ADAMTS7 | c.2373C>T p.I791= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1308175185; called by muse, mutect2, varscan2
- ADCK1 | c.285G>A p.K95= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV53082899; called by muse, mutect2, varscan2
- ADD1 | c.897C>G p.L299= | Silent (SNP) | VAF 62/163 reads (38%) | catalogued as COSV53271190; called by muse, mutect2, varscan2
- AFG1L | c.477A>G p.K159= | Silent (SNP) | VAF 37/55 reads (67%) | catalogued as COSV64555070, COSV64556736; called by muse, mutect2, varscan2
- AGAP3 | c.927C>T p.I309= (on ENST00000622464; = p.I345= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV58995253; called by muse, mutect2, varscan2
- ALKBH2 | c.12C>T p.F4= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as rs1480531371, COSV54357855; called by muse, mutect2, varscan2
- ANKRD13C | c.1416A>G p.V472= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV52032954; called by muse, mutect2, varscan2
- ANKRD36 | c.63C>T p.F21= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV70741536, COSV70743214; called by muse, mutect2, varscan2
- ARHGAP44 | c.1332C>T p.F444= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV52396745; called by muse, mutect2, varscan2
- ATP2C1 | c.1500G>A p.L500= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV60758950; called by muse, mutect2, varscan2
- C11orf65 | c.264T>C p.F88= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV67597979; called by muse, mutect2, varscan2
- C1RL | c.417C>T p.F139= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as COSV56925877; called by muse, mutect2, varscan2
- C6orf89 | c.438G>A p.Q146= (on ENST00000373685; = p.Q153= on NM_152734.4) | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs764965882, COSV62102445; called by muse, mutect2, varscan2
- CACNA1A | c.2232G>A p.Q744= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV64203883; called by muse, mutect2
- CAPRIN2 | c.1506G>A p.Q502= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as COSV51833818; called by muse, mutect2, varscan2
- CCDC151 | c.1173C>T p.L391= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV62698450; called by muse, mutect2, varscan2
- CCDC8 | c.1311G>A p.R437= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV56774037; called by muse, mutect2, varscan2
- CCDC88C | c.582C>T p.L194= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as COSV66239485; called by muse, mutect2, varscan2
- CDK6 | c.195G>A p.L65= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV56008319; called by muse, mutect2, varscan2
- CELSR2 | c.4818C>T p.G1606= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV54775526; called by muse, mutect2, varscan2
- CIB1 | c.318C>T p.I106= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV60174578; called by muse, mutect2, varscan2
- CLCNKA | c.1785G>A p.Q595= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV58892652; called by muse, varscan2
- CLUH | c.645G>A p.L215= (on ENST00000435359; = p.L253= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV70929414; called by muse, mutect2, varscan2
- CMYA5 | c.1173G>A p.L391= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV71407443; called by muse, mutect2, varscan2
- COG7 | c.2208C>T p.I736= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs762124832, COSV56151200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A1 | c.2160G>A p.R720= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV57887693; called by muse, mutect2, varscan2
- CRYM | c.837G>A p.V279= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV54832110; called by muse, mutect2
- CSMD2 | c.9984T>C p.D3328= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV53923740; called by muse, varscan2
- CWH43 | c.1935C>T p.I645= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV56940696; called by muse, mutect2, varscan2
- DDAH2 | c.837C>T p.L279= | Silent (SNP) | VAF 52/108 reads (48%) | catalogued as rs773004243, COSV65384170; called by muse, mutect2, varscan2
- DHCR7 | c.435C>T p.I145= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs941214871, COSV62795865; called by muse, mutect2, varscan2
- DPP8 | c.1731C>T p.I577= (on ENST00000341861 / NM_001320875.2; = p.I561= on NM_017743.6) | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV55680731; called by muse, mutect2, varscan2
- DR1 | c.189G>A p.K63= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV64725704; called by muse, mutect2
- DTWD2 | c.321G>A p.V107= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs1289936897, COSV58367630; called by muse, mutect2, varscan2
- DTX1 | c.288C>T p.F96= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1307204382, COSV57496170; called by muse, mutect2
- ERCC6L2 | c.550C>T p.L184= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as rs777114848, COSV56632400; called by muse, mutect2, varscan2
- EXOC7 | c.531C>T p.D177= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs779689081, COSV58743063; called by muse, mutect2, varscan2
- FBN2 | c.2979T>C p.R993= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV52527358, COSV99331368; called by muse, mutect2, varscan2
- FGF5 | c.666G>A p.S222= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as rs3733335, COSV56889628; called by muse, mutect2, varscan2
- FRYL | c.7881G>A p.L2627= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV51953140; called by muse, mutect2, varscan2
- GBP4 | c.1209G>A p.E403= | Silent (SNP) | VAF 61/154 reads (40%) | catalogued as rs777655424, COSV63255132; called by muse, mutect2, varscan2
- GLB1 | c.360G>A p.L120= | Silent (SNP) | VAF 45/72 reads (63%) | catalogued as COSV56565809; called by muse, mutect2, varscan2
- GSK3A | c.319C>T p.L107= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV55900027; called by muse, mutect2, varscan2
- H1-5 | c.48G>A p.E16= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as COSV58900684; called by muse, mutect2
- HELQ | c.2433C>T p.L811= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV55026235; called by muse, mutect2, varscan2
- HLA-C | c.261G>A p.E87= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV66115170; called by muse, mutect2, varscan2
- HOXB1 | c.618C>T p.L206= | Silent (SNP) | VAF 50/85 reads (59%) | catalogued as COSV53316340; called by muse, mutect2, varscan2
- HS3ST2 | c.432C>T p.G144= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV54464917; called by muse, mutect2, varscan2
- ITSN2 | c.1368A>G p.R456= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV61950394; called by muse, mutect2, varscan2
- JCAD | c.3072T>C p.S1024= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as COSV64760623; called by muse, mutect2, varscan2
- KCNJ1 | c.327C>T p.L109= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as rs775785177, COSV60662219; called by muse, mutect2, varscan2
- LAMA4 | c.2442C>T p.S814= (on ENST00000230538 / NM_001105206.3; = p.S807= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/43 reads (70%) | catalogued as COSV57900779; called by muse, mutect2, varscan2
- LDB1 | c.960G>A p.K320= (on ENST00000425280 / NM_001321612.2; = p.K284= on NM_003893.5) | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs1252764389, COSV63289538; called by muse, mutect2, varscan2
- LRIT2 | c.870G>A p.L290= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV60564308; called by muse, mutect2
- LRRC52 | c.687G>A p.G229= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV54232814; called by muse, mutect2, varscan2
- MAN1A2 | c.414G>A p.Q138= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV62977196; called by muse, mutect2, varscan2
- MB21D2 | c.1134C>T p.F378= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs748456390, COSV66664585; called by muse, mutect2, varscan2
- MRPL41 | c.306G>A p.K102= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV53002073; called by muse, mutect2, varscan2
- MRPL58 | c.351G>A p.Q117= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV56901470; called by muse, mutect2, varscan2
- MTFR1L | c.351G>A p.L117= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV65356106; called by muse, mutect2, varscan2
- NKX3-2 | c.834G>A p.K278= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs771741782, COSV66711845; called by muse, mutect2
- NPBWR1 | c.906C>T p.L302= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV58696461; called by muse, mutect2, varscan2
- NPC1L1 | c.3501C>G p.L1167= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV56927290; called by muse, mutect2
- NSD2 | c.1494G>A p.Q498= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1215743851, COSV56393241; called by muse, mutect2, varscan2
- OTOA | c.1293C>T p.L431= (on ENST00000286149; = p.L417= on NM_144672.4) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV53758726; called by muse, mutect2, varscan2
- OVCH1 | c.975A>C p.G325= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV58965347; called by muse, varscan2
- PAMR1 | c.627C>T p.S209= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV53514187; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PELO | c.438C>T p.L146= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs1324850419, COSV50879892; called by muse, mutect2, varscan2
- PLA2G4F | c.2469C>T p.V823= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as COSV51827995; called by muse, mutect2, varscan2
- PLEK | c.9A>G p.P3= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV52252793; called by muse, mutect2, varscan2
- PRPF40B | c.2028C>T p.F676= (on ENST00000380281; = p.F663= on NM_012272.3) | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV53304486; called by muse, mutect2, varscan2
- PTPN4 | c.2637T>C p.Y879= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV55304824; called by muse, mutect2, varscan2
- RARG | c.789C>G p.L263= | Silent (SNP) | VAF 72/224 reads (32%) | catalogued as COSV58433665, COSV58434837; called by muse, varscan2
- RASAL3 | c.2883G>A p.L961= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV54609592; called by muse, mutect2, varscan2
- RASSF2 | c.699G>A p.Q233= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV65082566; called by muse, mutect2, varscan2
- RASSF6 | c.408C>T p.D136= (on ENST00000342081 / NM_201431.2; = p.D104= on NM_177532.5) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs564196327, COSV56719588; called by muse, mutect2, varscan2
- RC3H1 | c.300G>A p.K100= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV51198866, COSV51205656; called by muse, mutect2, varscan2
- RCN3 | c.986G>A p.*329= | Silent (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- REEP1 | c.453C>T p.F151= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV51256169, COSV51257781; called by muse, mutect2, varscan2
- RELCH | c.822T>G p.L274= | Silent (SNP) | VAF 30/48 reads (63%) | catalogued as COSV56888440; called by muse, mutect2, varscan2
- RNF168 | c.1542A>T p.S514= | Silent (SNP) | VAF 89/287 reads (31%) | catalogued as COSV58838678; called by muse, mutect2, varscan2
- ROBO2 | c.3220C>T p.L1074= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs143136849, COSV59923121; called by muse, mutect2, varscan2
- RRAS | c.357G>T p.V119= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV55868805; called by muse, mutect2, varscan2
- RXRB | c.1536C>T p.L512= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV59499260; called by muse, mutect2, varscan2
- SCPEP1 | c.1314G>A p.G438= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV51854950; called by muse, mutect2, varscan2
- SFPQ | c.924C>T p.I308= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV61758348, COSV61758934; called by muse, mutect2, varscan2
- SHANK2 | c.2088C>T p.V696= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs782421767, COSV53607614; called by muse, mutect2, varscan2
- SLC16A1 | c.1431T>G p.V477= | Silent (SNP) | VAF 58/136 reads (43%) | catalogued as COSV63709792; called by muse, mutect2, varscan2
- SLC44A4 | c.270C>T p.N90= | Silent (SNP) | VAF 45/74 reads (61%) | catalogued as COSV57668097; called by muse, mutect2, varscan2
- SMUG1 | c.483C>G p.V161= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV54539979; called by muse, mutect2, varscan2
- SNRNP200 | c.5604G>C p.L1868= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV55531174; called by muse, mutect2, varscan2
- SOWAHB | c.615G>A p.L205= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs916471391, COSV57554846; called by muse, mutect2, varscan2
- SPHK2 | c.1098C>T p.L366= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs551364710, COSV55335357; called by muse, mutect2, varscan2
- SRP68 | c.1359G>A p.E453= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV57163631; called by muse, mutect2, varscan2
- TBR1 | c.180G>A p.T60= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV67418360; called by muse, mutect2, varscan2
- TCHH | c.1584C>T p.L528= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as COSV64276171; called by muse, mutect2, varscan2
- TERF2 | c.429G>A p.L143= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV54748155; called by muse, mutect2, varscan2
- THBS2 | c.537C>T p.F179= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV64680354; called by muse, mutect2, varscan2
- THNSL1 | c.270C>A p.I90= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as COSV64479571; called by muse, mutect2, varscan2
- TMC6 | c.1804C>T p.L602= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV59809995, COSV59811031; called by muse, mutect2, varscan2
- TMEM177 | c.333G>A p.L111= | Silent (SNP) | VAF 87/256 reads (34%) | catalogued as COSV55609141; called by muse, mutect2, varscan2
- TRAV29DV5 | c.264C>T p.F88= | Silent (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- TRAV4 | c.105G>A p.V35= | Silent (SNP) | VAF 28/47 reads (60%) | called by muse, mutect2, varscan2
- TTN | c.98292C>T p.L32764= (on ENST00000591111; = p.L25340= on NM_003319.4) | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs748516187, COSV60180952; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TUFM | c.48C>T p.F16= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV57949032; called by muse, mutect2
- TXK | c.621G>A p.K207= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV51917481; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2289G>A p.L763= | Silent (SNP) | VAF 49/111 reads (44%) | catalogued as COSV54439582; called by muse, mutect2, varscan2
- UPK1A | c.225C>T p.F75= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV55878586; called by muse, mutect2, varscan2
- UROS | c.418C>T p.L140= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV64226059; called by muse, mutect2, varscan2
- USH1C | c.1062G>A p.E354= | Silent (SNP) | VAF 5/101 reads (5%) | catalogued as COSV50023319; called by muse, mutect2
- USP43 | c.879C>T p.F293= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV53304602; called by muse, mutect2, varscan2
- VWF | c.1971G>A p.V657= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV54626539; called by muse, mutect2, varscan2
- XIRP1 | c.2830C>T p.L944= | Silent (SNP) | VAF 40/55 reads (73%) | catalogued as rs778186616, COSV61139562; called by muse, mutect2, varscan2
- ZAN | c.4665C>T p.G1555= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs550673734, COSV61806668, COSV61812967; called by muse, mutect2, varscan2
- ZBTB18 | c.1431G>A p.Q477= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1295961097, COSV62397819; called by muse, mutect2, varscan2
- ZFYVE1 | c.1431G>A p.E477= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV59611806; called by muse, mutect2, varscan2
- ZNF182 | c.231C>T p.L77= | Silent (SNP) | VAF 26/31 reads (84%) | catalogued as rs1409198431, COSV59358296; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824388 T>A | 5'Flank (SNP) | VAF 7/8 reads (88%) | called by muse, varscan2
- AMACR | c.739+1214G>C | Intron (SNP) | VAF 24/93 reads (26%) | catalogued as COSV100162993; called by muse, mutect2, varscan2
- CAMKK2 | c.-169C>T | 5'UTR (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100242969, COSV61216151; called by muse, mutect2, varscan2
- EBAG9 | c.522-943G>A | Intron (SNP) | VAF 63/154 reads (41%) | catalogued as COSV61753329; called by muse, mutect2, varscan2
- HMGCL | c.750+935C>T | Intron (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85441C>T | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as rs537870223, COSV72275109; called by muse, mutect2, varscan2
- NBPF25P | n.2005T>C | RNA (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- PDGFB | c.63+3046C>T | Intron (SNP) | VAF 14/35 reads (40%) | catalogued as COSV58648514, COSV58649386, COSV58650156; called by muse, mutect2, varscan2
- PNKD | c.236+1027C>T | Intron (SNP) | VAF 24/51 reads (47%) | catalogued as COSV50308337; called by muse, mutect2, varscan2
- POLQ | chr3:121546611 G>A | 5'Flank (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- RRM2 | n.714C>T | RNA (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
- TMBIM6 | c.-31+539C>T | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57280251; called by muse, mutect2
- WIPI1 | c.1293+1614G>A | Intron (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100048351; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173865977 G>A | 5'Flank (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- ZNF133 | c.217+315C>T | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- ZNF135 | chr19:58059255 C>T | 5'Flank (SNP) | VAF 11/16 reads (69%) | catalogued as COSV56606228; called by muse, mutect2, varscan2
- ZNF141 | c.226+5788G>C | Intron (SNP) | VAF 36/74 reads (49%) | catalogued as COSV99549623; called by muse, mutect2, varscan2
